Somatic mutation profile of tumor specimen TCGA-CZ-5459-01A (aliquot TCGA-CZ-5459-01A-01D-1501-10) from TCGA case TCGA-CZ-5459, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 63.8 years (23,318 days).
Specimen TCGA-CZ-5459-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 428f0ebb-8089-400c-b55c-2ccd0e0d9346.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5459-11A (Solid Tissue Normal), aliquot TCGA-CZ-5459-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01d839d5-17ca-4148-9dc1-9cf97123cb79

The open-access MAF lists 96 somatic variants for this specimen: 74 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 19, Frame Shift Del 8, Frame Shift Ins 2, Splice Region 2, Nonsense Mutation 2, Translation Start Site 1, 3'UTR 1, Splice Site 1, Intron 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSF2 | c.925C>A p.L309M | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV51974599; called by muse, mutect2, varscan2
- ARFGEF1 | c.2009C>T p.S670L | Missense Mutation (SNP) | VAF 162/780 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV51618870; called by muse, mutect2, varscan2
- BRWD1 | c.6577G>T p.V2193F | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.387); catalogued as rs140524582, COSV59000861; called by muse, mutect2, varscan2
- C3 | c.2618G>A p.C873Y | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55582885, COSV55582905; called by muse, mutect2, varscan2
- CCDC61 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.653); catalogued as rs377161841, COSV54430665; called by muse, mutect2, varscan2
- CEP112 | c.983T>A p.V328D | Missense Mutation (SNP) | VAF 309/964 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV67145454; called by muse, mutect2, varscan2
- CHST9 | c.1226T>C p.V409A | Missense Mutation (SNP) | VAF 86/350 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs771813887, COSV52451908; called by muse, mutect2, varscan2
- CLDN7 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as COSV63039761; called by muse, mutect2
- COBLL1 | c.2436A>G p.I812M (on ENST00000392717; = p.I774M on NM_014900.5) | Missense Mutation (SNP) | VAF 210/662 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV52077910; called by muse, mutect2, varscan2
- CTNNA1 | c.471G>T p.V157= | Splice Region (SNP) | VAF 159/606 reads (26%) | catalogued as COSV57082705; called by muse, mutect2, varscan2
- CUX1 | c.508A>G p.N170D (on ENST00000292535 / NM_181552.4; = p.N181D on NM_001913.5) | Missense Mutation (SNP) | VAF 128/432 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV52919254; called by muse, mutect2, varscan2
- DST | c.15629A>C p.Q5210P (on ENST00000361203 / NM_001374722.1; = p.Q2798P on NM_015548.5) | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55046366; called by muse, mutect2, varscan2
- EHMT2 | c.3395G>A p.R1132Q | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as rs960243186, COSV57669566; called by muse, mutect2, varscan2
- FBN1 | c.7207A>C p.I2403L | Missense Mutation (SNP) | VAF 82/278 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.881); catalogued as COSV57333191; called by muse, mutect2, varscan2
- FKBPL | c.775G>C p.A259P | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64322966; called by muse, mutect2, varscan2
- GRXCR1 | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 16/464 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs1263286674, COSV67675475; called by muse, mutect2
- HCN3 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV64235517; called by muse, mutect2, varscan2
- HYOU1 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782455800, COSV68217605, COSV99064770; called by muse, mutect2, varscan2
- KIAA1109 | c.14015A>T p.N4672I | Missense Mutation (SNP) | VAF 134/428 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52697141; called by muse, mutect2, varscan2
- KITLG | c.420C>G p.F140L | Missense Mutation (SNP) | VAF 75/224 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57204530; called by muse, mutect2, varscan2
- KNTC1 | c.1070A>G p.Q357R | Missense Mutation (SNP) | VAF 119/436 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV61085346; called by muse, mutect2
- LIN54 | c.1772C>A p.S591Y | Missense Mutation (SNP) | VAF 153/511 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV61199788, COSV61203206; called by muse, mutect2, varscan2
- LMBRD2 | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 172/604 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs754351558, COSV56953295; called by muse, mutect2, varscan2
- MDGA2 | c.897G>A p.M299I (on ENST00000399232 / NM_001113498.2; = p.M1? on NM_182830.4) | Missense Mutation (SNP) | VAF 134/441 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV62120026; called by muse, mutect2, varscan2
- ME2 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 85/304 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV58425386; called by muse, mutect2, varscan2
- METTL3 | c.1495G>C p.D499H | Missense Mutation (SNP) | VAF 111/331 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52971767; called by muse, mutect2, varscan2
- MMP10 | c.1065A>T p.K355N | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99666312; called by muse, mutect2
- MMP11 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 24/80 reads (30%) | catalogued as COSV53155955; called by muse, varscan2
- MTUS1 | c.2527del p.Y843Ifs*2 | Frame Shift Del (DEL) | VAF 99/374 reads (26%) | catalogued as COSV50577199; called by mutect2, varscan2
- MYEOV | c.692G>C p.R231T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as COSV58295524; called by muse, mutect2
- NKRF | c.1148A>C p.Q383P | Missense Mutation (SNP) | VAF 66/118 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV58663140; called by muse, mutect2, varscan2
- NOCT | c.845T>C p.I282T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs1476084635, COSV54937220; called by muse, mutect2, varscan2
- NOSTRIN | c.661C>A p.Q221K (on ENST00000317647 / NM_001039724.4; = p.Q143K on NM_052946.3) | Missense Mutation (SNP) | VAF 126/345 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV58324759; called by muse, mutect2, varscan2
- OR4C16 | c.13A>T p.N5Y | Missense Mutation (SNP) | VAF 66/212 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV58944745; called by muse, mutect2, varscan2
- PACS1 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV57700588; called by muse, mutect2, varscan2
- PDE5A | c.1633-1G>T p.X545_splice | Splice Site (SNP) | VAF 44/141 reads (31%) | catalogued as COSV53347504; called by muse, mutect2, varscan2
- PFDN5 | c.350T>G p.I117S | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV54477329; called by muse, mutect2, varscan2
- PHF14 | c.1886G>C p.R629P | Missense Mutation (SNP) | VAF 160/505 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV68857752; called by muse, mutect2, varscan2
- PHLPP2 | c.1115C>A p.S372Y | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.467); catalogued as COSV62427794; called by muse, mutect2, varscan2
- PM20D1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV65649807; called by muse, mutect2, varscan2
- PPL | c.2237T>C p.L746P | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62051859; called by muse, varscan2
- PPL | c.2204T>C p.F735S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV62051868; called by muse, varscan2
- PROM2 | c.1576C>A p.P526T | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58301311; called by muse, mutect2, varscan2
- RBPJ | c.881A>G p.E294G | Missense Mutation (SNP) | VAF 103/359 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.637); catalogued as COSV60758046; called by muse, mutect2, varscan2
- RNF14 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 109/395 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV61662990; called by muse, mutect2, varscan2
- SCYL3 | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63048080; called by muse, mutect2
- SETD2 | c.5479T>C p.W1827R | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57454775; called by muse, mutect2
- SLC25A12 | c.165G>T p.K55N | Missense Mutation (SNP) | VAF 99/312 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV55537991; called by muse, mutect2, varscan2
- SLC52A2 | c.1271T>C p.F424S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100095441; called by muse, varscan2
- SMCR8 | c.263A>G p.N88S | Missense Mutation (SNP) | VAF 91/248 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767917908, COSV58179645; called by muse, mutect2, varscan2
- SORBS2 | c.1314C>G p.I438M | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV53018993; called by muse, mutect2, varscan2
- TALDO1 | c.623C>A p.P208H | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV59796893; called by muse, mutect2, varscan2
- THBS1 | c.2136C>A p.H712Q | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as COSV52956462; called by muse, mutect2, varscan2
- TMED6 | c.175T>A p.F59I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV54749560; called by muse, mutect2, varscan2
- TMOD3 | c.230C>A p.A77E | Missense Mutation (SNP) | VAF 83/242 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57946859; called by muse, mutect2, varscan2
- TOP2A | c.4535C>T p.S1512F | Missense Mutation (SNP) | VAF 94/301 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.671); catalogued as COSV68503251; called by muse, mutect2, varscan2
- TP53BP1 | c.2600C>A p.S867* | Nonsense Mutation (SNP) | VAF 82/286 reads (29%) | catalogued as COSV55511364; called by muse, mutect2, varscan2
- TTN | c.49535G>A p.C16512Y (on ENST00000591111; = p.C9088Y on NM_003319.4) | Missense Mutation (SNP) | VAF 49/194 reads (25%) | PolyPhen probably damaging (0.998); catalogued as COSV60410097; called by muse, mutect2, varscan2
- UBAP2 | c.1867C>A p.H623N | Missense Mutation (SNP) | VAF 83/288 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV62549408; called by muse, mutect2, varscan2
- URGCP | c.2207C>A p.A736D (on ENST00000453200 / NM_001077663.3; = p.A727D on NM_017920.4) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV56253871, COSV99787244; called by muse, mutect2
- XPO5 | c.2985T>C p.D995= | Splice Region (SNP) | VAF 46/170 reads (27%) | catalogued as COSV54836055; called by muse, mutect2
- ZFPM2 | c.1877T>G p.I626S | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.054); catalogued as COSV65876545, COSV65876562; called by muse, mutect2, varscan2
- ZNF304 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 119/388 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56586839, COSV99988589; called by muse, mutect2, varscan2
- ABHD3 | c.699del p.I233Mfs*7 | Frame Shift Del (DEL) | VAF 59/226 reads (26%) | called by mutect2, pindel, varscan2
- ERN1 | c.2545del p.I849* | Frame Shift Del (DEL) | VAF 23/91 reads (25%) | called by mutect2, pindel, varscan2
- GPR141 | c.564del p.F188Lfs*3 | Frame Shift Del (DEL) | VAF 140/589 reads (24%) | called by mutect2, pindel, varscan2
- KDM2B | c.750_754del p.W251Pfs*33 | Frame Shift Del (DEL) | VAF 42/141 reads (30%) | called by mutect2, pindel, varscan2
- KRT12 | c.694dup p.I232Nfs*39 | Frame Shift Ins (INS) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- OR8B8 | c.255del p.F85Lfs*3 | Frame Shift Del (DEL) | VAF 69/300 reads (23%) | called by mutect2, pindel, varscan2
- PDXK | c.293_294del p.V98Afs*15 | Frame Shift Del (DEL) | VAF 25/112 reads (22%) | called by pindel, varscan2
- RC3H2 | c.1299del p.F433Lfs*13 | Frame Shift Del (DEL) | VAF 136/467 reads (29%) | called by mutect2, pindel, varscan2
- RDM1 | c.37A>T p.S13C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- VHL | c.378dup p.G127Wfs*5 | Frame Shift Ins (INS) | VAF 102/252 reads (40%) | called by mutect2, pindel, varscan2
- ZNF546 | c.647_649del p.S216del | In Frame Del (DEL) | VAF 61/234 reads (26%) | called by mutect2, pindel, varscan2
- CDC42BPA | c.4866T>C p.P1622= (on ENST00000334218 / NM_001366019.2; = p.P1609= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/146 reads (26%) | catalogued as COSV62024822; called by muse, mutect2, varscan2
- CIT | c.5841C>T p.P1947= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV55886361; called by muse, mutect2, varscan2
- COQ8A | c.1341G>A p.L447= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV64659647; called by muse, mutect2, varscan2
- DAB2 | c.984T>C p.S328= | Silent (SNP) | VAF 47/168 reads (28%) | catalogued as COSV57912879, COSV57919862; called by muse, mutect2, varscan2
- FOXA2 | c.1068G>A p.P356= (on ENST00000377115 / NM_153675.3; = p.P362= on NM_021784.5) | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs777713858, COSV65797253; called by muse, mutect2, varscan2
- GFRA2 | c.843G>A p.T281= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs773188702, COSV60782477; called by muse, mutect2, varscan2
- GHDC | c.1365T>C p.N455= | Silent (SNP) | VAF 46/149 reads (31%) | catalogued as COSV53187686; called by muse, mutect2, varscan2
- KCNH6 | c.1227G>A p.A409= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs764333218, COSV59006744; called by muse, mutect2, varscan2
- KDM4C | c.2160G>A p.K720= | Silent (SNP) | VAF 91/299 reads (30%) | catalogued as COSV67194642; called by muse, mutect2, varscan2
- MAP3K4 | c.3852T>C p.S1284= | Silent (SNP) | VAF 62/207 reads (30%) | catalogued as COSV62339845; called by muse, mutect2, varscan2
- MBD4 | c.1377T>C p.L459= | Silent (SNP) | VAF 114/230 reads (50%) | catalogued as COSV51446158; called by muse, varscan2
- MYOT | c.1209T>A p.T403= | Silent (SNP) | VAF 107/366 reads (29%) | catalogued as COSV51802538; called by muse, mutect2, varscan2
- NDUFB9 | c.483T>A p.G161= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV52676595; called by muse, mutect2, varscan2
- NUDT12 | c.801T>G p.V267= | Silent (SNP) | VAF 71/251 reads (28%) | catalogued as COSV50093457; called by muse, mutect2, varscan2
- OR2F1 | c.654C>T p.Y218= | Silent (SNP) | VAF 148/479 reads (31%) | catalogued as COSV67332203; called by muse, mutect2, varscan2
- PLEKHH1 | c.3243T>A p.S1081= | Silent (SNP) | VAF 54/161 reads (34%) | catalogued as COSV61288523; called by muse, mutect2, varscan2
- SLC16A3 | c.246G>C p.V82= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV66430327; called by muse, varscan2
- SRP68 | c.1212G>A p.R404= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV57165227; called by muse, mutect2, varscan2
- TMPRSS6 | c.1527C>T p.N509= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs758508265, COSV60984783; called by muse, mutect2, varscan2
- MIR519C | n.42C>T | RNA (SNP) | VAF 56/246 reads (23%) | called by muse, mutect2, varscan2
- ST20-MTHFS | c.-12+677A>G | Intron (SNP) | VAF 32/102 reads (31%) | catalogued as COSV72103153; called by muse, mutect2
- UVSSA | c.*8787G>A | 3'UTR (SNP) | VAF 6/30 reads (20%) | catalogued as COSV61352066; called by muse, mutect2, varscan2
